Somatic mutation profile of tumor specimen TCGA-AA-3530-01A (aliquot TCGA-AA-3530-01A-01W-0995-10) from TCGA case TCGA-AA-3530, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 80.5 years (29,402 days).
Specimen TCGA-AA-3530-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 530fb799-3e21-4dfe-9b8b-2b39bd6b5d8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3530-11A (Solid Tissue Normal), aliquot TCGA-AA-3530-11A-01D-1554-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e9b5bb4-ee5a-48e4-8765-e1fc322c8dc3

The open-access MAF lists 100 somatic variants for this specimen: 78 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 21, Nonsense Mutation 6, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1, Intron 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4405C>T p.Q1469* | Nonsense Mutation (SNP) | VAF 49/65 reads (75%) | catalogued as rs1060503288, CX106560, COSV57332774; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NFIA | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as rs1064794841, COSV64538077; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1528G>A p.G510R | Missense Mutation (SNP) | VAF 290/618 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61688753, COSV61690376; called by muse, mutect2, varscan2
- ACSL6 | c.428A>T p.K143I (on ENST00000379240; = p.K168I on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV99734814; called by muse, mutect2, varscan2
- AHCYL1 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.39); catalogued as COSV63209465; called by muse, mutect2, varscan2
- AL136295.1 | c.1771C>G p.L591V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.832); catalogued as COSV99938346; called by muse, mutect2, varscan2
- AMER1 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 259/293 reads (88%) | catalogued as COSV100367055, COSV57658549; called by muse, mutect2, varscan2
- ANK2 | c.3809C>A p.P1270H | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100004544; called by muse, mutect2, varscan2
- ANO4 | c.55+1G>T p.X19_splice | Splice Site (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100153991; called by muse, mutect2, varscan2
- ARHGAP17 | c.2440dup p.Q814Pfs*41 (on ENST00000289968 / NM_001006634.3; = p.Q736Pfs*41 on NM_018054.6) | Frame Shift Ins (INS) | VAF 15/108 reads (14%) | catalogued as rs773922861; called by mutect2, varscan2
- ATM | c.4466G>A p.R1489H | Missense Mutation (SNP) | VAF 434/1152 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs201594549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP12A | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 116/281 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs771710901, COSV54517004; called by muse, mutect2, varscan2
- ATP2B3 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as rs1412756906, COSV54842683; called by muse, mutect2, varscan2
- BRWD1 | c.3976G>A p.V1326M | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as COSV100314293; called by muse, varscan2
- C5 | c.3335A>G p.Q1112R | Missense Mutation (SNP) | VAF 189/433 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99798910; called by muse, mutect2, varscan2
- CACNG4 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 230/562 reads (41%) | catalogued as COSV100047967; called by muse, mutect2, varscan2
- CATSPER1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 107/452 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1033780625, COSV100375988, COSV56412522; called by muse, mutect2, varscan2
- CCKAR | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.243); catalogued as COSV55161165; called by muse, mutect2, varscan2
- CCM2L | c.275C>A p.T92N | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.526); catalogued as COSV52953022; called by muse, mutect2, varscan2
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 106/296 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2, varscan2
- CLDN18 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs1218344613, COSV51737591; called by muse, mutect2, varscan2
- COL27A1 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs144241003; called by muse, mutect2, varscan2
- COL6A6 | c.2707C>T p.R903W | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs768161608, COSV62026315; called by muse, mutect2, varscan2
- CRLF1 | c.1237A>G p.R413G | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs1304543330, COSV62261048; called by muse, mutect2, varscan2
- DNAH11 | c.4544T>C p.F1515S | Missense Mutation (SNP) | VAF 113/289 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100181199; called by muse, mutect2, varscan2
- FAT4 | c.616G>C p.G206R | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101272911; called by muse, varscan2
- FAT4 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV101272912; called by muse, varscan2
- FAT4 | c.5372C>A p.P1791Q | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100630436; called by muse, mutect2, varscan2
- FGF11 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.935); catalogued as COSV99548554; called by muse, mutect2, varscan2
- FNDC1 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV51931046; called by muse, mutect2, varscan2
- GRIN2A | c.3491C>T p.T1164M | Missense Mutation (SNP) | VAF 80/628 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.703); catalogued as COSV100408207, COSV58031456; called by muse, mutect2, varscan2
- IGF1R | c.1893G>T p.W631C | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99163375; called by muse, varscan2
- IGSF9B | c.3968C>T p.T1323M | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.143); catalogued as rs1279081770, COSV58073470; called by muse, mutect2, varscan2
- IGSF9B | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1369797597, COSV58071312; called by muse, mutect2, varscan2
- IQCB1 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 130/304 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as rs542335278, COSV60439721; called by muse, mutect2, varscan2
- IQCB1 | c.156T>G p.D52E | Missense Mutation (SNP) | VAF 131/306 reads (43%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV60439736; called by muse, mutect2, varscan2
- ITGAE | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs780520274; called by muse, mutect2, varscan2
- KCNG1 | c.461G>A p.W154* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100857193; called by muse, mutect2
- KCNRG | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 71/296 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV100078600; called by muse, mutect2, varscan2
- KCNRG | c.176G>T p.S59I | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100078601; called by muse, mutect2, varscan2
- KIF1A | c.2509G>A p.G837R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs768702963, COSV100242552, COSV57485318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT82 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs529536223, COSV57786136; called by muse, mutect2, varscan2
- LARGE1 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.394); catalogued as rs779336716, COSV100506516; called by muse, mutect2, varscan2
- LRP1 | c.4039G>A p.E1347K | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV54518660; called by muse, mutect2, varscan2
- MYH8 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs764777507, COSV67973466; called by muse, mutect2, varscan2
- MYPN | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs199476403, CM122987, COSV100590372; called by muse, mutect2, varscan2
- NANOS2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.45); catalogued as rs377721853, COSV58024701; called by muse, mutect2, varscan2
- NAP1L3 | c.666A>T p.E222D | Missense Mutation (SNP) | VAF 176/558 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV59077904; called by muse, mutect2, varscan2
- NLRP10 | c.1656G>T p.M552I | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100150016, COSV60778962; called by muse, mutect2, varscan2
- NRXN1 | c.2799C>A p.F933L | Missense Mutation (SNP) | VAF 43/361 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as COSV58497565; called by muse, mutect2, varscan2
- OR8K1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 92/602 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as rs775622719, COSV54403611, COSV54404718; called by muse, mutect2, varscan2
- POU2F1 | c.1271G>A p.R424H (on ENST00000541643 / NM_001365848.1; = p.R447H on NM_002697.4) | Missense Mutation (SNP) | VAF 441/579 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99612519; called by muse, mutect2, varscan2
- PRIMA1 | c.361A>C p.K121Q | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV60265943; called by muse, mutect2, varscan2
- PTPRT | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 140/246 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV100630980; called by muse, mutect2, varscan2
- RARB | c.421C>G p.Q141E (on ENST00000383772 / NM_001290216.2; = p.Q134E on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV58071324; called by muse, mutect2, varscan2
- REG3A | c.4C>G p.L2V | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV100532948; called by muse, mutect2
- SAP130 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52096192; called by muse, varscan2
- SCUBE2 | c.2485A>G p.N829D (on ENST00000649792 / NM_001367977.2; = p.N772D on NM_020974.3) | Missense Mutation (SNP) | VAF 54/564 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV100497010; called by muse, mutect2
- SHANK1 | c.6020C>T p.S2007L | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs374977074; called by muse, mutect2, varscan2
- SLC23A3 | c.1810G>A p.E604K (on ENST00000409878 / NM_001144889.2; = p.E487K on NM_144712.5) | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as COSV55409624; called by muse, mutect2, varscan2
- SOGA3 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 20/449 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64105059; called by muse, mutect2
- SPATA31D1 | c.4204G>T p.A1402S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV100782389, COSV61201866; called by muse, mutect2, varscan2
- TBX5 | c.38C>T p.T13M | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV59861620; called by muse, mutect2, varscan2
- THBS2 | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs368102843; called by muse, mutect2, varscan2
- TMPRSS11A | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs757090282, COSV58357045; called by muse, mutect2, varscan2
- TPO | c.2476G>A p.A826T | Missense Mutation (SNP) | VAF 208/496 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs781420871, COSV61100326; called by muse, mutect2, varscan2
- TSKS | c.498C>T p.S166= | Splice Region (SNP) | VAF 60/144 reads (42%) | catalogued as rs760112063, COSV55879976; called by muse, mutect2, varscan2
- VPS13A | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV100653651; called by muse, mutect2, varscan2
- WDFY3 | c.7430C>A p.A2477D | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV99885990; called by muse, mutect2, varscan2
- WDR36 | c.42G>T p.Q14H | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV72411524; called by muse, mutect2, varscan2
- XPR1 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 116/220 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs774173659, COSV62555583, COSV62560399; called by muse, mutect2, varscan2
- ZNF443 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 35/811 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1031068925, COSV100042424; called by muse, mutect2
- ZNF831 | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs139591279, COSV99057604; called by muse, mutect2, varscan2
- GSK3A | c.711_712del p.Q238Gfs*17 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- OR7A5 | c.849del p.M284Cfs*2 | Frame Shift Del (DEL) | VAF 27/208 reads (13%) | called by mutect2, pindel, varscan2
- TRABD | c.721_723del p.M241del | In Frame Del (DEL) | VAF 8/22 reads (36%) | called by pindel, varscan2
- UTP14A | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- AASS | c.958C>T p.L320= | Silent (SNP) | VAF 171/592 reads (29%) | catalogued as COSV62792144; called by muse, mutect2, varscan2
- AKT1 | c.693C>T p.N231= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs767346459, COSV62573945, COSV62576386; ClinVar: likely benign; called by muse, mutect2, varscan2
- AUTS2 | c.1614G>A p.T538= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV61385580; called by muse, mutect2, varscan2
- CNGB1 | c.3420C>T p.A1140= | Silent (SNP) | VAF 95/251 reads (38%) | catalogued as rs371860152, COSV51907804; called by muse, mutect2, varscan2
- DNAH11 | c.9279C>T p.S3093= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as rs200160729; called by muse, mutect2
- DNAH5 | c.5862A>G p.V1954= | Silent (SNP) | VAF 75/507 reads (15%) | catalogued as COSV54255482; called by muse, mutect2, varscan2
- GAS2 | c.429A>G p.R143= | Silent (SNP) | VAF 81/679 reads (12%) | catalogued as COSV53413189; called by muse, mutect2, varscan2
- GLI3 | c.3390C>T p.D1130= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs756608797, COSV67885638; called by muse, mutect2, varscan2
- HELQ | c.2787G>A p.K929= | Silent (SNP) | VAF 81/191 reads (42%) | catalogued as COSV55028264; called by muse, mutect2, varscan2
- HTR1A | c.1227C>T p.N409= | Silent (SNP) | VAF 70/497 reads (14%) | catalogued as rs1304433720, COSV60501135; called by muse, mutect2, varscan2
- IL17RD | c.2052G>A p.T684= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as rs1159304138, COSV56343456; called by muse, mutect2, varscan2
- MAGEC2 | c.207G>A p.E69= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99909499; called by muse, mutect2
- MMEL1 | c.576C>A p.I192= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99984568; called by muse, mutect2, varscan2
- MTG1 | c.858G>A p.T286= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs760541602, COSV58155397; called by muse, mutect2, varscan2
- MYO3A | c.3117C>T p.F1039= | Silent (SNP) | VAF 174/415 reads (42%) | catalogued as COSV56351448; called by muse, mutect2, varscan2
- REXO5 | c.324A>G p.L108= | Silent (SNP) | VAF 152/748 reads (20%) | catalogued as COSV54475090; called by muse, mutect2, varscan2
- RHOXF1 | c.255G>A p.P85= | Silent (SNP) | VAF 9/10 reads (90%) | catalogued as rs1295911130; called by muse, mutect2, varscan2
- RNF182 | c.426G>A p.P142= | Silent (SNP) | VAF 174/344 reads (51%) | catalogued as rs528284492, COSV70370128; called by muse, mutect2, varscan2
- SLC20A2 | c.939A>G p.R313= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV60607437; called by muse, mutect2, varscan2
- TRIM72 | c.546C>T p.F182= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs760762806, COSV57252367; called by muse, mutect2
- ZIC1 | c.372G>A p.S124= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV51553636, COSV99291455; called by muse, mutect2, varscan2
- ACOX1 | c.431-2659G>A | Intron (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
